Gene-level copy-number profile of tumor specimen TCGA-44-2657-01A from TCGA case TCGA-44-2657, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.7 years (27,298 days).
Specimen TCGA-44-2657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f7004720-899c-49bf-ae4f-dd0450e6196c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-2657-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a255b363-54bb-4263-887e-72501ea2d9a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 20,210; copy number 3: 11,379; copy number 4: 24,047; copy number 5: 1,055; copy number 6: 2,286; copy number 7: 197; copy number 8: 468; copy number 11: 1; copy number 12: 72; copy number 18: 89; copy number 20: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-2657-01A-01D-1877-01): tumor purity 0.34, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 178 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,570,771–107,459,564, 15 genes, copy number 20: RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:107,509,803–107,511,721, 1 gene, copy number 20: AL121957.1.
- chr12:25,385,670–28,581,511, 72 genes, copy number 12 (within-gene range 7–12) (broad region; genes not listed).
- chr12:57,055,643–60,419,293, 90 genes, copy number 11–18 (within-gene range 2–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
